Somatic mutation profile of tumor specimen ALCH-AE94-TTP1-A (aliquot ALCH-AE94-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AE94, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 84.0 years (30,668 days).
Specimen ALCH-AE94-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9a8a41f-babe-4987-aca8-78d755952704.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE94-NB1-A (Blood Derived Normal), aliquot ALCH-AE94-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37a9c6bc-8533-472e-9627-a33c3e23d928

The open-access MAF lists 78 somatic variants for this specimen: 53 protein-altering or splice-affecting, 18 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Nonsense Mutation 6, Intron 3, 5'UTR 3, In Frame Del 2, Splice Site 2, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 383/1257 reads (30%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 219/648 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 64/502 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247184; called by muse, mutect2, varscan2
- CTTNBP2 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV50445813; called by muse, mutect2, varscan2
- DAAM2 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1433665493; called by muse, varscan2
- FAM71B | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV57228073; called by muse, mutect2, varscan2
- FBN1 | c.693C>A p.C231* | Nonsense Mutation (SNP) | VAF 66/485 reads (14%) | catalogued as CM144995; called by muse, mutect2, varscan2
- GPR174 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as rs1260298080; called by muse, mutect2, varscan2
- IGKV1D-16 | c.330C>A p.C110* | Nonsense Mutation (SNP) | VAF 75/618 reads (12%) | catalogued as rs758557083; called by muse, mutect2, varscan2
- ITGA8 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 34/260 reads (13%) | catalogued as COSV100958899, COSV65227780; called by muse, mutect2, varscan2
- LIPK | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 70/487 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs376629947; called by muse, mutect2, varscan2
- MBNL2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs377182361; called by muse, varscan2
- NEUROG3 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 182/591 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV54343113; called by muse, mutect2, varscan2
- NRDE2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs761383323, COSV62962982; called by muse, mutect2, varscan2
- OR2L8 | c.353C>A p.A118D | Missense Mutation (SNP) | VAF 68/624 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100594018; called by muse, varscan2
- PCDH1 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 148/532 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs1219442685; called by muse, mutect2, varscan2
- PCDHA10 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 73/488 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.161); catalogued as COSV56481603; called by muse, mutect2, varscan2
- PICK1 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 60/503 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV63661831; called by muse, mutect2, varscan2
- PRR23D2 | c.150dup p.P51Tfs*27 | Frame Shift Ins (INS) | VAF 32/98 reads (33%) | catalogued as rs1200410038; called by mutect2, varscan2
- PTPRD | c.4117G>T p.E1373* | Nonsense Mutation (SNP) | VAF 29/266 reads (11%) | catalogued as COSV61951380; called by muse, mutect2, varscan2
- PXDN | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV53243418; called by muse, mutect2, varscan2
- SLIT2 | c.3025A>G p.N1009D | Missense Mutation (SNP) | VAF 121/461 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV104384450; called by muse, varscan2
- ST8SIA2 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | PolyPhen benign (0.003); catalogued as rs762911640, COSV51568730; called by muse, mutect2
- TLX3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs1464945279; called by muse, mutect2, varscan2
- TRPS1 | c.2956G>A p.D986N (on ENST00000220888 / NM_001330599.2; = p.D999N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV55253116, COSV99634958; called by muse, mutect2, varscan2
- UNC80 | c.9221G>A p.R3074H | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.579); catalogued as rs1413695148; called by muse, mutect2, varscan2
- VWF | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 74/476 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs61748471, CM910391; ClinVar: not provided; called by muse, mutect2, varscan2
- ZFHX4 | c.7228G>A p.A2410T | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs770276733, COSV50588067; called by muse, mutect2, varscan2
- ZNF488 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as rs782472727; called by muse, mutect2, varscan2
- ACADSB | c.24G>T p.L8F | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADCY3 | c.1346G>A p.G449D | Missense Mutation (SNP) | VAF 57/512 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR1 | c.1005C>A p.S335R | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CD36 | c.1006+1G>T p.X336_splice | Splice Site (SNP) | VAF 49/334 reads (15%) | called by muse, mutect2, varscan2
- CNGA4 | c.1355A>G p.E452G | Missense Mutation (SNP) | VAF 109/536 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- COL26A1 | c.953C>A p.P318H (on ENST00000313669 / NM_001278563.3; = p.P316H on NM_133457.4) | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNM2 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 76/558 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- FCGR2C | c.859del p.E287Kfs*8 | Frame Shift Del (DEL) | VAF 71/683 reads (10%) | called by mutect2, varscan2
- GAL3ST2 | c.288G>C p.W96C | Missense Mutation (SNP) | VAF 82/567 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- LZTS1 | c.1659G>C p.M553I | Missense Mutation (SNP) | VAF 101/537 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MYH4 | c.2599C>A p.L867M | Missense Mutation (SNP) | VAF 90/623 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- OR4A16 | c.332T>G p.F111C | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PBRM1 | c.646-2A>G p.X216_splice | Splice Site (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- PHYHIP | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.019); called by muse, varscan2
- RTN1 | c.1632G>T p.E544D | Missense Mutation (SNP) | VAF 156/710 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIN3A | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- STARD9 | c.2864C>A p.S955* | Nonsense Mutation (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- TET1 | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- TEX15 | c.1983A>T p.Q661H (on ENST00000256246; = p.Q1044H on NM_001350162.2) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TJP2 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC28 | c.5636C>A p.A1879D | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USH2A | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 110/805 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBED6 | c.673_675del p.D225del | In Frame Del (DEL) | VAF 34/316 reads (11%) | called by pindel, varscan2
- ZFYVE26 | c.6842C>G p.S2281* | Nonsense Mutation (SNP) | VAF 62/765 reads (8%) | called by muse, mutect2
- ACADSB | c.25C>T p.L9= | Silent (SNP) | VAF 43/399 reads (11%) | catalogued as rs1436730404; called by muse, mutect2, varscan2
- ACRV1 | c.21A>C p.L7= | Silent (SNP) | VAF 75/257 reads (29%) | called by muse, mutect2, varscan2
- ALMS1 | c.6426T>C p.F2142= | Silent (SNP) | VAF 59/253 reads (23%) | catalogued as rs760389784; called by muse, mutect2, varscan2
- CDC42BPA | c.1707C>T p.H569= | Silent (SNP) | VAF 78/628 reads (12%) | called by muse, varscan2
- COL1A2 | c.1041G>A p.E347= | Silent (SNP) | VAF 122/1057 reads (12%) | called by muse, mutect2, varscan2
- DES | c.183C>T p.G61= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV64661171; called by muse, mutect2, varscan2
- GANAB | c.177A>G p.P59= | Silent (SNP) | VAF 34/248 reads (14%) | called by muse, mutect2, varscan2
- IGLV5-45 | c.231G>A p.K77= | Silent (SNP) | VAF 77/755 reads (10%) | catalogued as rs370576104; called by muse, mutect2, varscan2
- KDM3A | c.3342T>C p.Y1114= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs537830749; called by muse, mutect2, varscan2
- OR14C36 | c.618C>T p.G206= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as rs767819229, COSV58602456; called by muse, mutect2, varscan2
- PAPPA2 | c.5149C>A p.R1717= | Silent (SNP) | VAF 52/339 reads (15%) | called by muse, mutect2, varscan2
- PATJ | c.4926C>T p.P1642= | Silent (SNP) | VAF 37/278 reads (13%) | called by muse, mutect2, varscan2
- PRNP | c.183T>C p.H61= | Silent (SNP) | VAF 72/299 reads (24%) | called by muse, mutect2, varscan2
- SPANXN2 | c.93G>A p.P31= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs782173002, COSV65127966; called by muse, mutect2, varscan2
- TLR4 | c.81G>A p.E27= | Silent (SNP) | VAF 80/563 reads (14%) | catalogued as rs200889734, COSV62923406; called by muse, mutect2, varscan2
- ULK1 | c.711G>A p.K237= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs1250102621; called by muse, mutect2
- VPS37D | c.219C>T p.P73= | Silent (SNP) | VAF 84/331 reads (25%) | called by muse, mutect2, varscan2
- ZNF280A | c.1488T>A p.T496= | Silent (SNP) | VAF 72/420 reads (17%) | called by muse, mutect2, varscan2
- DECR1 | c.69+3778G>T | Intron (SNP) | VAF 36/395 reads (9%) | called by muse, mutect2
- FAM53C | c.-170G>T | 5'UTR (SNP) | VAF 23/181 reads (13%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.-24C>A | 5'UTR (SNP) | VAF 14/117 reads (12%) | catalogued as rs1352947922; called by muse, mutect2
- PLXND1 | c.*781A>C | 3'UTR (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- RPS18 | c.-8C>T | 5'UTR (SNP) | VAF 45/262 reads (17%) | catalogued as rs374725351; called by muse, mutect2, varscan2
- SLIT2 | c.3088+54T>A | Intron (SNP) | VAF 101/354 reads (29%) | called by muse, varscan2
- THRB | c.284-12855T>C | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2
